Somatic mutation profile of tumor specimen MMRF_2230_1_BM_CD138pos (aliquot MMRF_2230_1_BM_CD138pos_T1_KHS5U_L08820) from MMRF case MMRF_2230, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 67.3 years (24,595 days).
Specimen MMRF_2230_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c9003652-23b3-4285-8b84-25c05d99673b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2230_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2230_1_PB_Whole_C2_KHS5U_L08787; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a45c25b0-b83b-4f05-b701-73b5359d1aa6

The open-access MAF lists 139 somatic variants for this specimen: 63 protein-altering or splice-affecting, 10 silent, 66 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, 3'UTR 39, Intron 15, Silent 10, 5'UTR 6, 5'Flank 4, Frame Shift Del 3, Nonsense Mutation 3, RNA 1, 3'Flank 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DSP | c.5212C>T p.R1738* | Nonsense Mutation (SNP) | VAF 7/142 reads (5%) | catalogued as rs794728124, CM150652, COSV65792473; ClinVar: pathogenic; called by muse, mutect2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 56/109 reads (51%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- ASB5 | c.830G>A p.S277N | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.11); catalogued as rs145702933, COSV56672746; called by muse, mutect2
- BRSK2 | c.22G>A p.G8S | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV57546893; called by muse, mutect2, varscan2
- CA4 | c.259G>A p.G87R | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs776961816, COSV56282811; called by muse, mutect2, varscan2
- CAPN12 | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 90/177 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs776565451, COSV61016468; called by muse, mutect2, varscan2
- CHST13 | c.433G>T p.A145S | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.454); catalogued as COSV60041215; called by muse, mutect2, varscan2
- CLDN20 | c.494A>G p.Y165C | Missense Mutation (SNP) | VAF 80/178 reads (45%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as rs752783633; called by muse, mutect2, varscan2
- DIS3 | c.2369T>C p.L790P | Missense Mutation (SNP) | VAF 50/110 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV66708371; called by muse, mutect2, varscan2
- DIS3 | c.1040G>A p.G347E | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66706787; called by muse, mutect2, varscan2
- DPP9 | c.278A>G p.K93R (on ENST00000598800; = p.K122R on NM_139159.5) | Missense Mutation (SNP) | VAF 28/141 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs754052696; called by muse, mutect2, varscan2
- F5 | c.2312T>A p.I771K | Missense Mutation (SNP) | VAF 60/231 reads (26%) | SIFT tolerated (0.84); PolyPhen benign (0.015); catalogued as COSV100889169; called by muse, mutect2, varscan2
- GABRG3 | c.1303C>G p.H435D | Missense Mutation (SNP) | VAF 68/159 reads (43%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.925); catalogued as COSV100404733; called by muse, mutect2, varscan2
- H1-4 | c.307G>C p.G103R | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104388637; called by muse, varscan2
- IGHV1OR21-1 | c.115G>T p.V39F | Missense Mutation (SNP) | VAF 26/265 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs774755868; called by mutect2, varscan2
- IGLV3-25 | c.155A>C p.Y52S | Missense Mutation (SNP) | VAF 67/154 reads (44%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs375402708; called by muse, mutect2, varscan2
- KDM3B | c.4876C>T p.R1626W | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100069791; called by muse, mutect2, varscan2
- MMP16 | c.164C>T p.P55L | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); catalogued as rs765641487, COSV99688820; called by muse, mutect2, varscan2
- NCK1 | c.434G>T p.R145L | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1347165787; called by muse, mutect2, varscan2
- NDST1 | c.2252G>A p.C751Y | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55786045; called by muse, mutect2, varscan2
- NF1 | c.4431G>A p.R1477= (on ENST00000358273 / NM_001042492.3; = p.R1456= on NM_000267.3) | Splice Region (SNP) | VAF 36/89 reads (40%) | catalogued as rs181462219; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR2H2 | c.716G>A p.C239Y | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63544561; called by muse, mutect2
- OR4C12 | c.802G>T p.A268S | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.259); catalogued as rs782056194, COSV58860976; called by muse, mutect2, varscan2
- OR5T2 | c.403G>A p.G135R | Missense Mutation (SNP) | VAF 37/133 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100506796; called by muse, mutect2, varscan2
- PCSK4 | c.2149G>A p.V717M | Missense Mutation (SNP) | VAF 39/74 reads (53%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs775533550; called by muse, mutect2, varscan2
- RUNDC1 | c.1765C>T p.R589C | Missense Mutation (SNP) | VAF 56/114 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375753180; called by muse, mutect2, varscan2
- RYR2 | c.3091C>T p.R1031C | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.947); catalogued as rs1438792084, COSV100771770; called by muse, mutect2
- TENM4 | c.158G>A p.R53H | Missense Mutation (SNP) | VAF 50/96 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as CM1511326, COSV53679592; called by muse, mutect2, varscan2
- TLN1 | c.6530G>A p.R2177Q | Missense Mutation (SNP) | VAF 81/170 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as rs1425752432, COSV59212812; called by muse, mutect2, varscan2
- TPH2 | c.1141C>T p.L381F | Missense Mutation (SNP) | VAF 61/133 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100421880; called by muse, mutect2, varscan2
- TSPOAP1 | c.4420del p.R1474Gfs*60 | Frame Shift Del (DEL) | VAF 20/93 reads (22%) | catalogued as COSV52109003; called by mutect2, pindel, varscan2
- UQCRH | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.96); catalogued as rs750228344, COSV61175982; called by muse, mutect2, varscan2
- YLPM1 | c.5513T>C p.I1838T | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1311771446; called by muse, mutect2, varscan2
- ZFYVE16 | c.1208A>G p.H403R | Missense Mutation (SNP) | VAF 84/156 reads (54%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as rs764075297; called by muse, mutect2, varscan2
- ZIM2 | c.1358G>A p.R453H | Missense Mutation (SNP) | VAF 62/127 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs186729168, COSV55636281; called by muse, mutect2, varscan2
- ACTC1 | c.381G>T p.E127D | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- ACTL10 | c.622G>C p.A208P | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ADGRG2 | c.1712T>C p.V571A (on ENST00000379869 / NM_001079858.3; = p.V568A on NM_005756.4) | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.48); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- BCR | c.8A>C p.D3A | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.255); called by muse, varscan2
- BSN | c.2529G>T p.M843I | Missense Mutation (SNP) | VAF 97/184 reads (53%) | SIFT tolerated (0.32); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- CCNT1 | c.952G>T p.E318* | Nonsense Mutation (SNP) | VAF 44/165 reads (27%) | called by muse, mutect2, varscan2
- EBF3 | c.135-2A>G p.X45_splice | Splice Site (SNP) | VAF 15/58 reads (26%) | called by muse, mutect2, varscan2
- ELFN1 | c.32T>G p.V11G | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- EPHB6 | c.583C>G p.L195V | Missense Mutation (SNP) | VAF 21/177 reads (12%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- GBP7 | c.671T>C p.I224T | Missense Mutation (SNP) | VAF 40/268 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- H1-4 | c.349A>G p.K117E | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.211); called by muse, varscan2
- HAAO | c.595C>G p.P199A | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IFT20 | c.80C>A p.T27N | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- L1TD1 | c.1628G>C p.S543T | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.27); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- LENG1 | c.322G>C p.E108Q | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- NFKB2 | c.1856T>A p.L619Q | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- OR8G1 | c.8G>C p.G3A | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PER1 | c.2804C>A p.P935H | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- RHOXF1 | c.139A>G p.N47D | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SERPINI1 | c.1107A>C p.Q369H | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SPATA21 | c.457C>G p.P153A | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TEX11 | c.1577C>G p.S526* (on ENST00000344304; = p.S511* on NM_031276.3) | Nonsense Mutation (SNP) | VAF 11/39 reads (28%) | called by muse, mutect2, varscan2
- TRBV5-7 | c.172C>A p.L58M | Missense Mutation (SNP) | VAF 30/174 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.569); called by muse, varscan2
- UGT2B7 | c.298C>T p.L100F | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- VEGFB | c.346del p.L116Wfs*18 | Frame Shift Del (DEL) | VAF 57/302 reads (19%) | called by mutect2, pindel, varscan2
- ZNF292 | c.7175G>T p.G2392V | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF410 | c.1016A>T p.H339L | Missense Mutation (SNP) | VAF 42/203 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZNF717 | c.1968del p.H657Ifs*21 | Frame Shift Del (DEL) | VAF 28/96 reads (29%) | called by pindel, varscan2
- GPNMB | c.1408C>T p.L470= (on ENST00000381990 / NM_001005340.2; = p.L458= on NM_002510.3) | Silent (SNP) | VAF 32/58 reads (55%) | catalogued as rs761436273; called by muse, mutect2, varscan2
- IGHV2-70 | c.141A>T p.S47= | Silent (SNP) | VAF 58/111 reads (52%) | catalogued as rs576478313; called by muse, varscan2
- KCNT1 | c.2110C>T p.L704= (on ENST00000488444; = p.L723= on NM_020822.3) | Silent (SNP) | VAF 3/44 reads (7%) | catalogued as COSV99704828; called by muse, mutect2
- KDF1 | c.927C>T p.S309= | Silent (SNP) | VAF 12/212 reads (6%) | called by muse, mutect2
- KDM6B | c.4239G>A p.V1413= | Silent (SNP) | VAF 79/324 reads (24%) | called by muse, mutect2, varscan2
- MPND | c.378C>G p.A126= | Silent (SNP) | VAF 37/140 reads (26%) | called by muse, mutect2, varscan2
- MRPL1 | c.582A>G p.A194= | Silent (SNP) | VAF 26/60 reads (43%) | catalogued as rs1373248820; called by muse, mutect2, varscan2
- PCDHA11 | c.1794G>A p.A598= | Silent (SNP) | VAF 30/76 reads (39%) | catalogued as rs372076650; called by muse, mutect2, varscan2
- SERPINA4 | c.822A>C p.A274= | Silent (SNP) | VAF 12/66 reads (18%) | called by muse, mutect2, varscan2
- ZFPM2 | c.2724C>T p.S908= | Silent (SNP) | VAF 108/207 reads (52%) | called by muse, mutect2, varscan2
- ABCC2 | c.*493C>T | 3'UTR (SNP) | VAF 33/75 reads (44%) | called by muse, mutect2, varscan2
- AC002428.1 | chr5:135922323 A>T | 5'Flank (SNP) | VAF 28/62 reads (45%) | called by muse, mutect2, varscan2
- AC092718.9 | chr16:81147302 C>T | 5'Flank (SNP) | VAF 21/55 reads (38%) | catalogued as rs774682358; called by muse, mutect2, varscan2
- ANKRD24 | c.-59A>T | 5'UTR (SNP) | VAF 17/31 reads (55%) | called by muse, mutect2, varscan2
- ANP32A | c.*163dup | 3'UTR (INS) | VAF 8/29 reads (28%) | catalogued as rs1217167847; called by mutect2, pindel, varscan2
- ARHGAP28 | c.*3063T>C | 3'UTR (SNP) | VAF 5/88 reads (6%) | called by muse, mutect2
- ASAH2 | c.*2375G>C | 3'UTR (SNP) | VAF 140/299 reads (47%) | called by muse, mutect2, varscan2
- ATG4C | c.*717T>C | 3'UTR (SNP) | VAF 25/64 reads (39%) | called by muse, mutect2, varscan2
- BRF1 | c.*77C>T | 3'UTR (SNP) | VAF 26/53 reads (49%) | catalogued as rs374972527; called by muse, mutect2, varscan2
- C20orf173 | c.-65A>T | 5'UTR (SNP) | VAF 169/378 reads (45%) | called by muse, mutect2, varscan2
- C5orf58 | chr5:170232841 C>T | 5'Flank (SNP) | VAF 95/193 reads (49%) | called by muse, mutect2, varscan2
- CCDC74B | c.*234T>A | 3'UTR (SNP) | VAF 41/207 reads (20%) | called by muse, mutect2, varscan2
- CHPF | c.*99G>A | 3'UTR (SNP) | VAF 14/32 reads (44%) | catalogued as rs1469139695; called by muse, mutect2, varscan2
- COL19A1 | c.*1245G>A | 3'UTR (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- CPED1 | c.249+4144A>G | Intron (SNP) | VAF 22/72 reads (31%) | catalogued as rs1168252516; called by muse, mutect2, varscan2
- CTSH | c.933-86T>C | Intron (SNP) | VAF 13/24 reads (54%) | called by muse, mutect2, varscan2
- DMTF1 | c.*97A>G | 3'UTR (SNP) | VAF 159/344 reads (46%) | called by muse, mutect2, varscan2
- EBF1 | c.*1920A>G | 3'UTR (SNP) | VAF 10/62 reads (16%) | called by muse, mutect2, varscan2
- EGFLAM | c.98-32063G>A | Intron (SNP) | VAF 54/161 reads (34%) | catalogued as rs1486377227; called by muse, mutect2
- EHF | c.*1094G>A | 3'UTR (SNP) | VAF 27/91 reads (30%) | called by muse, mutect2, varscan2
- EPHA5 | c.*3107T>A | 3'UTR (SNP) | VAF 49/98 reads (50%) | called by muse, mutect2, varscan2
- FBXO30-DT | n.667-18844T>G | Intron (SNP) | VAF 32/99 reads (32%) | called by muse, mutect2, varscan2
- FBXO32 | c.*4041T>A | 3'UTR (SNP) | VAF 28/68 reads (41%) | called by muse, mutect2, varscan2
- FRAS1 | c.*2776T>C | 3'UTR (SNP) | VAF 8/108 reads (7%) | called by muse, mutect2
- FSTL5 | c.*777G>A | 3'UTR (SNP) | VAF 22/122 reads (18%) | called by muse, mutect2, varscan2
- GCLM | c.*2308del | 3'UTR (DEL) | VAF 48/115 reads (42%) | catalogued as rs34571118; called by mutect2, varscan2
- GIMAP1 | c.*2456C>T | 3'UTR (SNP) | VAF 51/106 reads (48%) | called by muse, mutect2, varscan2
- GLI4 | c.223+244G>C | Intron (SNP) | VAF 72/280 reads (26%) | called by muse, mutect2, varscan2
- GLRA3 | c.*3135del | 3'UTR (DEL) | VAF 28/88 reads (32%) | catalogued as rs569067653; called by mutect2, varscan2
- GLRA3 | c.*3134A>T | 3'UTR (SNP) | VAF 28/84 reads (33%) | called by mutect2, varscan2
- GPC4 | c.-482G>A | 5'UTR (SNP) | VAF 4/11 reads (36%) | catalogued as rs974845264; called by muse, mutect2, varscan2
- HDAC11 | c.552+114T>C | Intron (SNP) | VAF 16/29 reads (55%) | called by muse, mutect2, varscan2
- HEY1 | c.331+55G>A | Intron (SNP) | VAF 8/28 reads (29%) | called by muse, mutect2, varscan2
- HMGB3 | c.*1033T>A | 3'UTR (SNP) | VAF 9/39 reads (23%) | called by muse, mutect2, varscan2
- HPF1 | c.737-103A>T | Intron (SNP) | VAF 4/15 reads (27%) | called by muse, mutect2, varscan2
- HTR1A | c.-330T>A | 5'UTR (SNP) | VAF 32/114 reads (28%) | called by muse, mutect2, varscan2
- IGFBP5 | c.*144C>T | 3'UTR (SNP) | VAF 24/49 reads (49%) | catalogued as rs1300212618; called by muse, mutect2, varscan2
- LY6K | c.*860C>T | 3'UTR (SNP) | VAF 14/58 reads (24%) | catalogued as rs1346261669; called by muse, mutect2, varscan2
- MDS2 | n.472G>A | RNA (SNP) | VAF 10/57 reads (18%) | catalogued as rs926220918; called by muse, mutect2, varscan2
- NSD2 | c.1881+3523A>T | Intron (SNP) | VAF 10/55 reads (18%) | called by muse, mutect2, varscan2
- OR12D2 | c.*69T>G | 3'UTR (SNP) | VAF 72/148 reads (49%) | called by muse, mutect2, varscan2
- PCMTD1 | c.308-4093A>G | Intron (SNP) | VAF 29/74 reads (39%) | catalogued as rs763147062; called by muse, mutect2, varscan2
- PIGP | c.*627del | 3'UTR (DEL) | VAF 79/203 reads (39%) | called by mutect2, pindel, varscan2
- REM1 | c.*160G>A | 3'UTR (SNP) | VAF 62/124 reads (50%) | catalogued as rs1290578891; called by muse, mutect2, varscan2
- RPS3A | c.62+174G>T | Intron (SNP) | VAF 10/56 reads (18%) | called by muse, mutect2, varscan2
- RTL6 | c.*1319G>A | 3'UTR (SNP) | VAF 52/104 reads (50%) | catalogued as rs890238374; called by muse, mutect2, varscan2
- SEPTIN11 | c.-120G>T | 5'UTR (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2, varscan2
- SFRP5 | c.*514C>T | 3'UTR (SNP) | VAF 30/54 reads (56%) | called by muse, mutect2, varscan2
- SLC27A4 | c.*254C>T | 3'UTR (SNP) | VAF 43/145 reads (30%) | catalogued as rs186434263; called by muse, mutect2, varscan2
- SLC38A2 | c.*2150A>T | 3'UTR (SNP) | VAF 63/115 reads (55%) | called by muse, mutect2, varscan2
- SLC38A2 | c.*2035T>G | 3'UTR (SNP) | VAF 44/91 reads (48%) | called by muse, varscan2
- SLCO1B3 | c.1865+800T>A | Intron (SNP) | VAF 43/125 reads (34%) | called by muse, mutect2, varscan2
- SLIT1 | c.*385G>T | 3'UTR (SNP) | VAF 18/63 reads (29%) | called by muse, mutect2, varscan2
- ST6GAL2 | c.*790T>A | 3'UTR (SNP) | VAF 28/62 reads (45%) | called by muse, mutect2, varscan2
- TAF8 | chr6:42048688 T>A | 5'Flank (SNP) | VAF 26/49 reads (53%) | called by muse, mutect2, varscan2
- TMEM40 | chr3:12734103 G>C | 3'Flank (SNP) | VAF 5/33 reads (15%) | called by muse, mutect2, varscan2
- TNFAIP3 | c.635-48A>T | Intron (SNP) | VAF 22/59 reads (37%) | called by muse, mutect2, varscan2
- TNRC6C | c.-114G>C | 5'UTR (SNP) | VAF 12/79 reads (15%) | called by muse, mutect2, varscan2
- TPT1 | c.102+245G>T | Intron (SNP) | VAF 16/81 reads (20%) | called by muse, mutect2, varscan2
- TTYH1 | c.1315-41C>G | Intron (SNP) | VAF 12/352 reads (3%) | called by muse, mutect2
- UBASH3B | c.*3949G>A | 3'UTR (SNP) | VAF 40/82 reads (49%) | called by muse, mutect2, varscan2
- WDR44 | c.*296A>G | 3'UTR (SNP) | VAF 5/61 reads (8%) | called by muse, mutect2
- XKR6 | c.*1036G>A | 3'UTR (SNP) | VAF 23/115 reads (20%) | catalogued as rs548733994; called by muse, mutect2, varscan2
- ZNF135 | c.*982T>A | 3'UTR (SNP) | VAF 4/70 reads (6%) | called by muse, mutect2
- ZNF202 | c.*678G>C | 3'UTR (SNP) | VAF 8/95 reads (8%) | called by muse, mutect2
- ZNF24 | c.*176G>T | 3'UTR (SNP) | VAF 41/85 reads (48%) | called by muse, mutect2, varscan2
